Gene-level copy-number profile of tumor specimen TCGA-V5-A7RC-01B from TCGA case TCGA-V5-A7RC, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; Tumor grade: GX; Age at diagnosis: 56.0 years (20,439 days).
Specimen TCGA-V5-A7RC-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.c17d8aca-2e43-4521-aefe-2c21b6f01e63.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V5-A7RC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b8ac04a6-3829-49f3-850e-7d0ebf0aa86e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 9,507; copy number 3: 20,540; copy number 4: 20,713; copy number 5: 4,569; copy number 6: 1,928; copy number 7: 115; copy number 8: 143; copy number 10: 45; copy number 11: 27; copy number 12: 170; copy number 13: 10; copy number 14: 1,118; copy number 15: 646; copy number 19: 45; copy number 20: 106; copy number 21: 81; copy number 23: 11; copy number 25: 9; copy number 34: 18; copy number 99: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V5-A7RC-01B-11D-A402-01): tumor purity 0.56, ploidy 3.7, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,296 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,799,422–40,862,363, 45 genes, copy number 11–99: AL033527.3, LINC02811, TRIT1, Y_RNA, MYCL, MYCL-AS1, Y_RNA, MFSD2A, AL663070.1, CAP1, PPT1, OAZ1P1, RLF, RNU6-1237P, TMCO2, AL050341.2, ZMPSTE24, AL050341.1, COL9A2, AL031985.2, SMAP2, AL031985.1, AL031985.4, ZFP69B, AL031985.3, AL603839.4, ZFP69, AL603839.3, EXO5, AL603839.1, AL603839.2, ZNF684, AL356379.2, AL356379.1, GTF2F2P2, RIMS3, AL031289.2, AL031289.1, NFYC-AS1, NFYC, MIR30E, MIR30C1, KCNQ4, RN7SL326P, CITED4.
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 12–15 (broad region; genes not listed).
- chr6:42,155,406–45,664,349, 107 genes, copy number 13–25 (broad region; genes not listed).
- chr11:69,294,151–72,843,674, 130 genes, copy number 14–23 (within-gene range 2–23) (broad region; genes not listed).
- chr12:65,278,643–75,390,928, 169 genes, copy number 14–34 (within-gene range 3–34) (broad region; genes not listed).
- chr19:58,278,955–58,605,223, 45 genes, copy number 10 (within-gene range 6–10): ZNF8, ZNF8-ERVK3-1, ERVK3-1, AC010642.2, AC010642.1, ZSCAN22, MIR6806, A1BG, AC012313.3, A1BG-AS1, AC012313.10, ZNF497, AC012313.2, AC012313.6, RNA5SP473, ZNF837, RPS5, MIR4754, RNF225, LINC02560, ZNF584, AC012313.1, AC012313.4, AC012313.5, ZNF132, AC012313.8, ZNF324B, ZNF324, ZNF446, AC012313.7, SLC27A5, RNU6-1337P, RN7SL693P, AC012313.9, ZBTB45, RN7SL525P, TRIM28, MIR6807, CHMP2A, UBE2M, MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
